Gene-level copy-number profile of tumor specimen ALCH-AEZR-TTP1-A from ALCHEMIST case ALCH-AEZR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 45.0 years (16,452 days).
Specimen ALCH-AEZR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 845206f2-92eb-47df-b267-7e9f442712e3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEZR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/da5172c2-2c7d-4eb2-a5df-61f8f366cccb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 1: 1,178; copy number 2: 55,838; copy number 3: 1,087; copy number 4: 168; copy number 5: 13; copy number 6: 1; copy number 7: 1; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:944,203–959,309, 1 gene (within-gene range 0–1): NOC2L.
- chr1:3,059,615–3,068,437, 1 gene: PRDM16-DT.
- chr2:9,757,496–9,770,341, 1 gene: AC082651.3.
- chr2:238,100,340–238,168,900, 4 genes: ESPNL, KLHL30, KLHL30-AS1, ERFE.
- chr3:52,812,962–52,835,729, 3 genes (within-gene range 0–2): ITIH4, AC006254.1, ITIH4-AS1.
- chr4:49,588,772–49,589,529, 1 gene: SNX18P25.
- chr5:69,068,925–69,069,200, 1 gene: SUMO2P4.
- chr6:34,576,258–34,576,656, 1 gene: IFITM3P3.
- chr7:4,775,615–4,794,397, 3 genes: AP5Z1, MIR4656, AC092610.1.
- chr7:4,811,188–4,811,289, 1 gene (within-gene range 0–2): Y_RNA.
- chr9:124,257,606–124,353,307, 3 genes (within-gene range 0–2): NEK6, AL162724.2, AL162724.1.
- chr10:128,958,772–128,960,062, 1 gene: AL355537.1.
- chr10:133,374,736–133,374,869, 1 gene: AL360181.4.
- chr11:1,828,307–1,837,521, 1 gene: SYT8.
- chr13:113,297,239–113,364,148, 4 genes (within-gene range 0–1): LAMP1, GRTP1, AL136221.1, GRTP1-AS1.
- chr15:25,169,337–25,239,919, 39 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38.
- chr15:41,851,913–41,852,029, 1 gene (within-gene range 0–2): RNA5SP393.
- chr15:78,752,107–78,753,373, 1 gene: AC022748.1.
- chr16:8,847,650–8,869,012, 4 genes (within-gene range 0–2): AC012173.1, AC022167.2, CARHSP1, AC022167.1.
- chr16:89,268,104–89,273,044, 1 gene (within-gene range 0–2): AC137932.3.
- chr17:2,689,386–2,723,947, 4 genes (within-gene range 0–2): CLUH, MIR6776, AC005696.1, AC005696.4.
- chr17:16,414,524–16,437,003, 3 genes (within-gene range 0–2): AC093484.2, TRPV2, AC093484.1.
- chr17:22,090,743–22,221,605, 2 genes: UBBP4, FTLP13.
- chr17:65,538,102–65,641,033, 1 gene (within-gene range 0–2): AC004805.1.
- chr22:18,846,811–18,861,049, 2 genes: AC008132.1, BCRP7.
- chr22:21,001,886–21,044,117, 8 genes (within-gene range 0–2): THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649.
- chr22:36,440,880–36,440,970, 1 gene: Y_RNA.
- chr22:41,922,032–41,926,806, 2 genes: TNFRSF13C, MIR378I.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:2,854,031–2,854,107, 1 gene, copy number 6: MIR4645.
- chr7:57,067,950–57,074,664, 1 gene, copy number 7: AC122133.1.
- chr7:74,773,962–74,789,376, 1 gene, copy number 15: NCF1.
- chr7:100,539,203–100,586,129, 5 genes, copy number 5 (within-gene range 2–5): AGFG2, IRS3P, SAP25, AC069281.2, LRCH4.
- chr8:142,620,373–142,621,064, 1 gene, copy number 5: AP006547.1.
- chr11:799,179–832,883, 5 genes, copy number 5 (within-gene range 1–5): PIDD1, RPLP2, SNORA52, PNPLA2, AP006621.1.
- chr11:2,944,431–2,992,377, 2 genes, copy number 5 (within-gene range 2–5): NAP1L4, SNORA54.

Autosomal genes at a single copy (total copy number 1): 1,178. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
